Surgical pathology report (de-identified scan), TCGA case TCGA-BA-4075, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site UNC, specimen TCGA-BA-4075-01A (Primary Tumor).

[page 1 of 5]
SURGICAL PATHOLOGY

Surgical Pathology Report

Diagnosis:

- A: Tongue and mandible, total glossectomy.
- Invasive squamous cell carcinoma.
- Histologic grade: Moderately differentiated, with surface necrosis.
- No in situ component identified.
- Tumor size: 6.0 cm
- Depth of invasion: 1.3 cm
- Invasion of associated minor salivary gland: Positive.
- Lymphovascular invasion: Positive.
- Perineural invasion: Positive, extensive.
- Associated bone: Negative for tumor.
- Lymph nodes: Negative (0/10).
- Margins: Positive (tumor undermines intact mucosa at anterior margin). All other margins are negative.
- B: Right neck Level II lymph nodes, removal.
- Negative for tumor (0/17).
- C: Right neck Level III lymph nodes, removal.
- Negative for tumor (0/11).
- D: Right neck Level IV lymph nodes, removal.
- Negative for tumor (0/5).
- Benign skeletal muscle.
- E: Right neck Level V lymph nodes, removal.
- Negative for tumor (0/5).
- F: Porta-cath, removal.
- Catheter.
- Gross evaluation only

[page 2 of 5]
Clinical History:
persistent tongue cancer.

Gross Description:
Received are six appropriately labeled containers.

Container A:

Specimen fixation: formalin

Type of specimen: total glossectomy with neck dissection

Size of specimen: The specimen consists of a composite resection consisting of right mandible (8.5 x 3.5 x 0.9 cm) and the entire tongue (14.0 x 6.0 x 3.0 cm). Attached to the inferior aspect of the mandible is a pedicle of yellow/tan soft tissue that measures 6.5 x 2.0 x 0.8 cm.

Orientation of specimen: The specimen is not oriented. The margins are inked as follows: anterior/green, posterior/blue, lateral/orange, inferior/yellow, deep/black

Tumor description: grayish/white, ulcerative lesion

Location of tumor: The tumor is situated at the tongue root, right floor of the mouth, and right tonsillar fossa.

Tumor size: 6.0 x 2.5 x 1.5 cm

Extent of tumor: The tumor extends along the entire right lateral mucosal surface to grossly involve the anterior soft tissue margin of resection. On cut section, the tumor extends into the vertical muscle of the tongue to a depth of 1.3 cm.

Presence/absence of bone involvement: The tumor abuts the submandibular fossa, does not grossly appear to be invading into the bone.

Distance of tumor from surgical margins: The tumor grossly involves the anterior soft tissue margin of resection.

Description of remainder of tissue: Embedded within the soft tissue pedicle, extending from the inferior aspect of

[page 3 of 5]
the mandible, are seven apparent tan/brown lymph nodes that measure up to 0.4 cm. In addition, the inferior aspect of the mandible has what appears to be a segment of possible submandibular gland that measures 2.0 x 1.0 x 0.6 cm; on cut section, two additional apparent lymph nodes are identified that measure up to 0.4 cm. Elsewhere, the soft tissues are unremarkable.

Tissue submitted for special investigations: A small portion of tumor and normal tissue are given to Tissue Procurement.

Block Summary:

A1 - left lateral gingival margin, en face
A2 - anterior soft tissue margin, en face
A3,A4 - right palatoglossal and palatopharyngeal soft tissue margins, en face
A5,A6 - posterior soft tissue margin, en face
A7 - inferior medial mucosal margin, en face
A8 - additional inferior margin, en face
A9 - representative deep soft tissue margin
A10 - posterior bone margin, en face
A11 - anterior bone margin, en face
A12,A13 - representative sections of tumor
A14 - representative section of tumor and bone
A15,A16 - additional sections of tumor
A17 - grossly unremarkable tongue
A18 - six apparent lymph nodes from soft tissue pedicle
A19 - two apparent lymph nodes from soft tissue pedicle
A20-A22 - remainder of soft tissue pedicle, entirely submitted
A23 - representative section of possible submandibular gland with single apparent lymph node
A24 - representative section of possible submandibular gland with second individual apparent lymph node

Container B is additionally labeled "right neck, Level II lymph nodes." It holds a fragment of tan/yellow soft tissue that measures 12.5 x 4.5 x 1.5 cm. Embedded within the soft tissue are 18 apparent tan/brown lymph nodes that range in size from a few mm's up to 1.0 cm.

B1 - eleven apparent lymph nodes, entirely submitted
B2 - five apparent lymph nodes, entirely submitted
B3 - two apparent lymph nodes, entirely submitted

[page 4 of 5]
Container C is additionally labeled "right neck, Level III."

It holds a portion of brown/gray soft tissue that measures 7.0 x 2.5 x 1.5 cm. Embedded within the soft tissue are eight apparent tan/brown lymph nodes that range in size from a few mm' s up to 1.1 cm.

C1 - six apparent lymph nodes, entirely submitted

C2 - two apparent lymph nodes, entirely submitted

Container D is additionally labeled "right neck, Level IV."

It holds a portion of yellow/brown skeletal muscle that measures 5.0 x 3.5 x 2.5 cm. A small amount of adipose tissue is attached to the external surface. Embedded within the adipose tissue are six apparent tan/brown lymph nodes that range in size from a few mm' s up to 1.2 cm. The attached surface of the skeletal muscle is unremarkable.

D1 - four apparent lymph nodes, entirely submitted

D2 - single apparent bisected lymph node, entirely submitted

D3 - single bisected apparent lymph node, entirely submitted

Container E is additionally labeled "right neck, Level V."

It holds a fragment of yellow/tan soft tissue that measures 5.5 x 3.0 x 1.3 cm. Embedded within the soft tissue are five apparent tan lymph nodes that range in size from 0.3 up to 0.8 cm. (Block E1, [REDACTED])

Container F is additionally labeled "porta-cath." It holds a white metal reservoir that measures 2.0 x 2.0 x 1.0 cm. Attached to the reservoir is a white plastic catheter that measures 26.5 cm in length and 0.2 cm in diameter. Inscribed on the back of the metal reservoir in the following information: Bard E03125. The specimen is for Gross only.

Light Microscopy:

Light microscopic examination is performed by Dr.

(Specimen A)

Histologic tumor type: Invasive squamous cell carcinoma

[page 5 of 5]
Histologic grade: moderately differentiated, superficial necrosis

Tumor extent: invades 1.3 cm in to skeletal muscle, involves minor salivary gland

Presence/absence of CIS: absent

Presence/absence of angiolymphatic space invasion: present

Presence/absence of perineural space invasion: present, extensive

Histologic assessment of surgical margins: positive anterior

(A2, invasive tumor undermines intact mucosa) all other margins and bone are negative.

Lymph nodes: total 0/48

A. 0/10, 4 show partial fibrosis

B. 0/17, 6 show partial fibrosis.

C. 0/11, 1 with partial fibrosis

D. 0/5, no fibrosis

E. 0/5, no fibrosis

AJCC staging:

PT3

PN0

pMX

This staging information is based on this pathologic specimen and may be incomplete. A comprehensive review of all available information is recommended to determine final staging.

Source: NCI Genomic Data Commons file b5b755bf-bef7-474e-9532-a4401ce6323a (TCGA-BA-4075.D71F3395-4B46-458A-8A51-0130AA40FFAD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).